Somatic mutation profile of tumor specimen 0DHKQD from CCDI case PBBUPJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.9 years (2,524 days).
Specimen 0DHKQD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d8ecb17-621b-45c3-9d4a-595d1cf712a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHKP2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ee25a8-78c7-41e1-9179-760df5d1b161

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALU | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369749257; called by muse, mutect2
- COL7A1 | c.3457C>T p.R1153C | Missense Mutation (SNP) | VAF 234/443 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375583602; called by muse, mutect2, varscan2
- HP | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs779931784, COSV63325886; called by muse, mutect2, varscan2
- PRAMEF11 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 68/679 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs765965471; called by muse, mutect2
- TRAM1L1 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as rs1387744594, COSV60293437; called by muse, mutect2, varscan2
- WT1 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as CM1213320, COSV60076425; called by muse, mutect2, varscan2
- XYLT1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs776038981, COSV99760497; called by muse, mutect2, varscan2
- ZNF730 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1319053829; called by muse, mutect2
- DOCK1 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- PRAMEF9 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RAVER2 | c.1230G>C p.Q410H (on ENST00000294428 / NM_001366165.1; = p.X398_splice on NM_018211.4) | Missense Mutation (SNP) | VAF 93/160 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC15A2 | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 26/536 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- TARDBP | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 101/335 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PLAGL2 | c.595C>A p.R199= | Silent (SNP) | VAF 19/335 reads (6%) | catalogued as rs761517519; called by muse, mutect2
- PLIN3 | c.621G>A p.T207= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as rs759408719; called by muse, mutect2, varscan2
- SLC22A5 | c.237C>T p.H79= | Silent (SNP) | VAF 227/483 reads (47%) | catalogued as rs781684339; called by muse, mutect2, varscan2
- STOX2 | c.1758C>T p.G586= | Silent (SNP) | VAF 55/342 reads (16%) | catalogued as rs748013023; called by muse, mutect2, varscan2
- TOPBP1 | c.3819A>G p.S1273= | Silent (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- TTC6 | c.534C>A p.V178= | Silent (SNP) | VAF 33/533 reads (6%) | called by muse, mutect2
- ANK1 | c.-58C>T | 5'UTR (SNP) | VAF 58/327 reads (18%) | called by muse, mutect2, varscan2
- MAP1S | c.-5C>G | 5'UTR (SNP) | VAF 15/184 reads (8%) | catalogued as rs977552955; called by muse, mutect2
- PDE5A | c.1396+40T>A | Intron (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- TSPAN32 | c.544-34C>G | Intron (SNP) | VAF 20/55 reads (36%) | called by muse, varscan2
